Somatic mutation profile of tumor specimen TCGA-93-A4JP-01D (aliquot TCGA-93-A4JP-01D-01D-A38P-08) from TCGA case TCGA-93-A4JP, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.7 years (23,620 days).
Specimen TCGA-93-A4JP-01D: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bafa95b-ff5b-45d0-b1c7-e3ab5b0aa7c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-A4JP-10A (Blood Derived Normal), aliquot TCGA-93-A4JP-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29eb1aa5-1358-43cd-a53a-8cad3837e688

The open-access MAF lists 121 somatic variants for this specimen: 93 protein-altering or splice-affecting, 28 silent.
By variant classification: Missense Mutation 82, Silent 28, Nonsense Mutation 5, Frame Shift Del 3, In Frame Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 46/105 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | hotspot (GDC flag); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.2631C>G p.D877E | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV101275991; called by muse, mutect2, varscan2
- ABCB9 | c.1073A>T p.Q358L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99757790; called by muse, mutect2, varscan2
- ADCY10 | c.2444C>A p.S815Y | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV100896950; called by muse, mutect2, varscan2
- AGER | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100426221, COSV61248342; called by muse, mutect2, varscan2
- AHNAK | c.14768T>A p.L4923* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | catalogued as COSV99948322; called by muse, mutect2, varscan2
- ARHGEF17 | c.2076G>T p.W692C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.237); catalogued as COSV99735159; called by muse, mutect2, varscan2
- ASPM | c.7056G>C p.M2352I | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.474); catalogued as COSV54124482, COSV54126118; called by muse, mutect2, varscan2
- C11orf71 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100348401; called by muse, mutect2, varscan2
- C16orf72 | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100589078; called by muse, mutect2, varscan2
- CCKAR | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.4); catalogued as rs1332889950, COSV55160385; called by muse, mutect2, varscan2
- CEMIP | c.2880C>A p.D960E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779315054, COSV99586948; called by muse, mutect2, varscan2
- CES1 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1469938147; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 48/117 reads (41%) | catalogued as COSV100291935; called by muse, mutect2, varscan2
- COL15A1 | c.3112G>C p.E1038Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.403); catalogued as COSV100897846; called by muse, mutect2, varscan2
- CPA1 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1554411117, COSV99163282; called by muse, varscan2
- CYP2W1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs577187426; called by muse, mutect2, varscan2
- DCHS1 | c.5239C>T p.H1747Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1341701938; called by muse, mutect2, varscan2
- FAM181A | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs1210196399, COSV50888079, COSV99967891; called by muse, mutect2, varscan2
- FAM193A | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV61193901; called by muse, mutect2, varscan2
- GABRG1 | c.53G>A p.S18N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as rs1308305437, COSV99778365; called by muse, mutect2, varscan2
- GADD45B | c.390G>T p.W130C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV99077691; called by muse, mutect2, varscan2
- GJA1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs755535373, CM166276; called by muse, mutect2, varscan2
- GRM5 | c.2339C>T p.T780M | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1173489364, COSV59603502; called by muse, mutect2, varscan2
- GTF3C3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.037); catalogued as COSV99826813; called by muse, mutect2
- ITGAM | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54935825; called by muse, mutect2, varscan2
- KATNIP | c.551G>T p.R184I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99851494; called by muse, mutect2, varscan2
- KCNH4 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV99237524; called by muse, mutect2, varscan2
- KREMEN1 | c.694G>A p.D232N (on ENST00000407188; = p.D234N on NM_032045.5) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs748122732, COSV59913049; called by muse, mutect2, varscan2
- LYSMD4 | c.168C>G p.H56Q (on ENST00000409796 / NM_001284417.2; = p.T27R on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1172339874; called by muse, mutect2, varscan2
- MON2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99742975; called by muse, mutect2, varscan2
- MYB | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100214989; called by muse, mutect2, varscan2
- MYO5C | c.3323A>G p.K1108R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1314407313, COSV55907661; called by muse, mutect2, varscan2
- OBSCN | c.1442A>T p.Q481L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV99481217; called by muse, mutect2, varscan2
- OPTN | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs779278597, CD1512216, COSV99537622; called by muse, mutect2, varscan2
- OR4A5 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs769709798; called by mutect2, varscan2
- ORC2 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554714404, COSV99309502, COSV99309612; called by muse, mutect2, varscan2
- PCDH11Y | c.2665C>A p.P889T (on ENST00000400457 / NM_032973.2; = p.P878T on NM_032971.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99291648, COSV99291958; called by muse, mutect2, varscan2
- PCDHB6 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV50701615; called by muse, mutect2, varscan2
- PCNX1 | c.6898T>A p.W2300R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99456281; called by muse, mutect2, varscan2
- PIGF | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs1235565060; called by muse, varscan2
- PIK3R4 | c.3925A>T p.K1309* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100650511; called by muse, mutect2, varscan2
- PMS1 | c.1962A>G p.I654M | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100575715; called by muse, mutect2, varscan2
- PPP1R13L | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV62908419; called by muse, mutect2, varscan2
- PRX | c.2926G>T p.E976* | Nonsense Mutation (SNP) | VAF 65/125 reads (52%) | catalogued as COSV99397814; called by muse, mutect2, varscan2
- PRX | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99397821; called by muse, mutect2, varscan2
- PRXL2A | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100939814; called by muse, varscan2
- PTPRZ1 | c.2990C>T p.S997F | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs777223716, COSV101100409; called by muse, mutect2, varscan2
- RAB25 | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as rs1233927006; called by muse, mutect2, varscan2
- RABEP1 | c.2128A>C p.K710Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV99336819; called by muse, mutect2, varscan2
- RB1 | c.1049G>T p.S350I | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1368390928, COSV57300027; called by muse, mutect2, varscan2
- RBM6 | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as rs770294018; called by muse, mutect2, varscan2
- SGO1 | c.1631C>T p.S544L (on ENST00000263753 / NM_001012410.5; = p.S275L on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | PolyPhen benign (0.003); catalogued as rs1446600479, COSV55425432; called by muse, mutect2, varscan2
- SPATA25 | c.267C>G p.N89K | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV99509977; called by muse, mutect2, varscan2
- SPN | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs201256378, COSV64071238; called by muse, mutect2, varscan2
- STAB1 | c.2914C>T p.R972W | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745991082, COSV58731711; called by muse, mutect2, varscan2
- SYNE1 | c.21335C>T p.A7112V (on ENST00000367255 / NM_182961.4; = p.A7041V on NM_033071.3) | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1458770104, COSV99570682; called by muse, mutect2, varscan2
- TBL3 | c.1433A>T p.H478L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100224968; called by muse, mutect2, varscan2
- THADA | c.1984T>G p.W662G | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV57676200; called by muse, mutect2, varscan2
- TMEM175 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99297705; called by muse, mutect2, varscan2
- TNS3 | c.3230A>G p.H1077R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1488977299; called by muse, mutect2, varscan2
- TSGA10 | c.959T>C p.I320T | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs768295810; called by muse, mutect2, varscan2
- ZBTB9 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101221778; called by muse, mutect2, varscan2
- ZKSCAN2 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100048265; called by muse, mutect2
- ZNF485 | c.730T>C p.C244R | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700239; called by muse, mutect2, varscan2
- BAD | c.113A>T p.H38L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD101 | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CHD6 | c.6106_6107del p.D2036Rfs*5 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by pindel, varscan2
- DHX40 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FZD10 | c.955T>C p.F319L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GADD45B | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- IGKV2D-30 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- LRP1B | c.3753T>A p.S1251R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- LYSMD4 | c.169A>C p.K57Q (on ENST00000409796 / NM_001284417.2; = p.T27= on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NRG3 | c.951T>C p.C317= | Splice Region (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- PAXBP1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAXBP1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- PAXBP1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- POLDIP3 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- POMGNT1 | c.1903_1905del p.K635del | In Frame Del (DEL) | VAF 12/40 reads (30%) | called by pindel, varscan2
- PPM1A | c.330A>C p.E110D | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSMD1 | c.2202_2218+12del p.X734_splice | Splice Site (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- RIMS2 | c.3329C>A p.P1110Q (on ENST00000666250 / NM_001348490.2; = p.P918Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD2 | c.2083T>G p.L695V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2
- SETD5 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SIAH2 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- SIDT2 | c.193del p.V65Cfs*5 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- SLC52A3 | c.390G>C p.M130I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STXBP6 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- VRK2 | c.1326C>A p.F442L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDHD1 | c.3031C>G p.Q1011E | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF408 | c.127_130del p.V43Hfs*11 | Frame Shift Del (DEL) | VAF 23/133 reads (17%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.126C>T p.F42= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs772729752, COSV68334760; called by muse, mutect2, varscan2
- ARL10 | c.696C>T p.T232= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs755526248; called by muse, mutect2, varscan2
- BRCA1 | c.4938C>T p.V1646= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV100524627; called by muse, mutect2, varscan2
- CKAP4 | c.1692G>A p.S564= | Silent (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- COL6A2 | c.2817C>T p.H939= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs368164391; called by muse, mutect2, varscan2
- DNAH8 | c.4866A>G p.A1622= | Silent (SNP) | VAF 16/197 reads (8%) | called by muse, mutect2
- DRG1 | c.990C>T p.I330= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100513720; called by muse, mutect2, varscan2
- EPHB2 | c.1944C>T p.I648= (on ENST00000400191 / NM_001309193.2; = p.I649= on NM_004442.7) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs748061214; called by mutect2, varscan2
- GABRA6 | c.636A>T p.G212= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99194696; called by muse, mutect2
- GALNT7 | c.669C>A p.L223= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs1009992683; called by muse, mutect2, varscan2
- GRIN2B | c.660C>G p.L220= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV101663210, COSV74205600; called by muse, mutect2, varscan2
- LTBP3 | c.921C>T p.I307= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1444052671; called by muse, mutect2, varscan2
- NTPCR | c.333C>T p.V111= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as COSV100786727; called by muse, mutect2, varscan2
- OR11G2 | c.402C>A p.G134= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs915819617, COSV100639989; called by muse, mutect2, varscan2
- OR4K15 | c.369C>A p.A123= (on ENST00000305051; = p.A99= on NM_001005486.1) | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV100520957, COSV59300713; called by muse, mutect2, varscan2
- PCDHGB3 | c.1719G>A p.A573= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV53954936, COSV54070104; called by muse, mutect2, varscan2
- PKHD1L1 | c.12381C>A p.L4127= | Silent (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- RERG | c.435C>T p.Y145= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV57005590; called by muse, mutect2, varscan2
- SELPLG | c.915C>A p.V305= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV57311418, COSV57313419; called by muse, mutect2, varscan2
- SGPP1 | c.606C>T p.Y202= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs756929891, COSV99905900; called by muse, mutect2, varscan2
- SI | c.579G>A p.K193= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV100016223, COSV52298220; called by muse, mutect2, varscan2
- SLC6A15 | c.1530G>C p.L510= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV57026272; called by muse, mutect2, varscan2
- STAB1 | c.2775G>C p.V925= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100401949; called by muse, varscan2
- TAF6L | c.297C>G p.L99= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV99585295; called by muse, mutect2, varscan2
- THBS2 | c.363G>A p.A121= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs112534076, COSV100827897; called by muse, mutect2, varscan2
- UBA6 | c.393A>T p.P131= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV100451775; called by muse, varscan2
- WNK4 | c.1341C>T p.D447= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs775815906; called by muse, mutect2, varscan2
- XDH | c.1839G>A p.R613= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV65151760; called by muse, mutect2, varscan2
